Somatic mutation profile of tumor specimen TCGA-B9-A5W9-01A (aliquot TCGA-B9-A5W9-01A-11D-A28G-10) from TCGA case TCGA-B9-A5W9, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Age at diagnosis: 40.2 years (14,668 days).
Specimen TCGA-B9-A5W9-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 53bdc62b-f1e4-4e6d-8db7-954fb608b538.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-B9-A5W9-10A (Blood Derived Normal), aliquot TCGA-B9-A5W9-10A-01D-A28G-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b2688a74-b59f-4973-ab86-9bf4fc814142

The open-access MAF lists 54 somatic variants for this specimen: 42 protein-altering or splice-affecting, 12 silent.
By variant classification: Missense Mutation 34, Silent 12, Frame Shift Del 5, Nonsense Mutation 2, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACACB | c.6877G>A p.V2293M | Missense Mutation (SNP) | VAF 50/91 reads (55%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV58143571; called by muse, mutect2, varscan2
- ADGRG3 | c.496C>T p.P166S | Missense Mutation (SNP) | VAF 22/77 reads (29%) | SIFT tolerated (0.15); PolyPhen benign (0.022); catalogued as COSV59652261; called by muse, mutect2, varscan2
- ANLN | c.711A>C p.K237N | Missense Mutation (SNP) | VAF 45/82 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); catalogued as COSV56078786; called by muse, mutect2, varscan2
- ARFGEF3 | c.6275G>A p.R2092K | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT tolerated, low confidence (0.24); PolyPhen probably damaging (0.952); catalogued as COSV52468069; called by muse, mutect2, varscan2
- BPIFB4 | c.1535A>T p.K512I | Missense Mutation (SNP) | VAF 75/159 reads (47%) | SIFT deleterious (0.02); PolyPhen benign (0.136); catalogued as COSV64952090; called by muse, mutect2, varscan2
- CATSPER4 | c.503T>A p.L168H | Missense Mutation (SNP) | VAF 27/75 reads (36%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.87); catalogued as COSV58794264; called by muse, mutect2, varscan2
- CEP85L | c.2207G>A p.R736H | Missense Mutation (SNP) | VAF 21/100 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs371610026, COSV63827091; called by muse, mutect2, varscan2
- CLEC18B | c.1048C>A p.L350M | Missense Mutation (SNP) | VAF 82/405 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV60578559; called by muse, mutect2, varscan2
- CPE | c.251A>C p.E84A | Missense Mutation (SNP) | VAF 80/133 reads (60%) | SIFT deleterious (0.04); PolyPhen benign (0.185); catalogued as COSV68582180; called by muse, mutect2, varscan2
- ECI2 | c.443A>C p.D148A (on ENST00000380118 / NM_206836.3; = p.D118A on NM_006117.2) | Missense Mutation (SNP) | VAF 21/78 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.197); catalogued as COSV60988439; called by muse, mutect2, varscan2
- HFM1 | c.3424G>C p.E1142Q | Missense Mutation (SNP) | VAF 29/79 reads (37%) | SIFT tolerated (0.29); PolyPhen benign (0.034); catalogued as COSV54035135; called by muse, mutect2, varscan2
- HIGD2A | c.230T>A p.L77H | Missense Mutation (SNP) | VAF 33/127 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.961); catalogued as COSV51257888; called by muse, mutect2, varscan2
- ISLR | c.866G>T p.G289V | Missense Mutation (SNP) | VAF 63/111 reads (57%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.889); catalogued as COSV51434913; called by muse, mutect2, varscan2
- ITGB5 | c.1603T>A p.C535S | Missense Mutation (SNP) | VAF 27/72 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV56152237; called by muse, mutect2, varscan2
- KDM2B | c.2433G>T p.E811D | Missense Mutation (SNP) | VAF 9/51 reads (18%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0.007); catalogued as COSV65644145; called by muse, mutect2
- KIAA1210 | c.4754A>C p.K1585T | Missense Mutation (SNP) | VAF 6/43 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.883); catalogued as COSV68179456; called by muse, mutect2, varscan2
- KMT2D | c.8978T>G p.L2993R | Missense Mutation (SNP) | VAF 46/161 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV56476183; called by muse, mutect2, varscan2
- LRRC25 | c.116G>C p.S39T | Missense Mutation (SNP) | VAF 73/174 reads (42%) | SIFT tolerated (0.76); PolyPhen benign (0); catalogued as COSV59115817; called by muse, mutect2, varscan2
- MYO15A | c.8323C>T p.R2775C | Missense Mutation (SNP) | VAF 10/96 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs770282862, COSV52763480; called by muse, mutect2, varscan2
- PEBP1 | c.240A>C p.K80N | Missense Mutation (SNP) | VAF 21/66 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.071); catalogued as COSV54337698, COSV54337715; called by muse, mutect2, varscan2
- RAB5B | c.424A>G p.M142V | Missense Mutation (SNP) | VAF 79/135 reads (59%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as rs1191940197, COSV64365162; called by muse, mutect2, varscan2
- RGL1 | c.1938T>G p.N646K (on ENST00000360851 / NM_001297672.2; = p.N681K on NM_015149.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 38/86 reads (44%) | SIFT tolerated (0.69); PolyPhen benign (0.018); catalogued as COSV58993766; called by muse, mutect2, varscan2
- RHEBL1 | c.349G>T p.V117L | Missense Mutation (SNP) | VAF 61/102 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV56504873; called by muse, varscan2
- RLF | c.2024G>A p.G675D | Missense Mutation (SNP) | VAF 18/43 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65652887; called by muse, mutect2, varscan2
- SCPEP1 | c.114A>C p.E38D | Missense Mutation (SNP) | VAF 147/314 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.97); catalogued as COSV51855334; called by muse, mutect2, varscan2
- SDHD | c.91A>G p.I31V | Missense Mutation (SNP) | VAF 25/57 reads (44%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV54779192; called by muse, mutect2, varscan2
- SLC17A8 | c.1344T>G p.I448M | Missense Mutation (SNP) | VAF 66/95 reads (69%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV60126077; called by muse, mutect2, varscan2
- SLC18A2 | c.160G>T p.E54* | Nonsense Mutation (SNP) | VAF 26/59 reads (44%) | catalogued as COSV53689447, COSV53692914; called by muse, mutect2, varscan2
- SPTB | c.3482G>A p.S1161N | Missense Mutation (SNP) | VAF 28/72 reads (39%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as rs768901063, COSV67634467; called by muse, mutect2
- SPTBN5 | c.4739T>G p.L1580R | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58026552; called by muse, mutect2, varscan2
- STK11IP | c.1922T>C p.V641A | Missense Mutation (SNP) | VAF 32/83 reads (39%) | SIFT tolerated (0.29); PolyPhen benign (0.006); catalogued as COSV55254299; called by muse, mutect2, varscan2
- TNFRSF21 | c.331C>T p.Q111* | Nonsense Mutation (SNP) | VAF 55/124 reads (44%) | catalogued as COSV57284602; called by muse, mutect2, varscan2
- UNC5A | c.914T>G p.L305R | Missense Mutation (SNP) | VAF 59/101 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56171664; called by muse, mutect2, varscan2
- ZNF443 | c.1124A>G p.D375G | Missense Mutation (SNP) | VAF 35/117 reads (30%) | SIFT tolerated (0.4); PolyPhen possibly damaging (0.908); catalogued as rs749828521, COSV56893700; called by muse, mutect2, varscan2
- AATF | c.1056G>A p.M352I | Missense Mutation (SNP) | VAF 79/147 reads (54%) | SIFT tolerated (0.44); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- AL136295.1 | c.1638_1660del p.G548Lfs*96 | Frame Shift Del (DEL) | VAF 61/192 reads (32%) | called by mutect2, pindel, varscan2
- DOCK3 | c.4312del p.V1438Yfs*14 | Frame Shift Del (DEL) | VAF 56/198 reads (28%) | called by mutect2, pindel, varscan2
- HERC2 | c.7032del p.Q2345Sfs*34 | Frame Shift Del (DEL) | VAF 110/286 reads (38%) | called by mutect2, varscan2
- KANSL2 | c.400del p.S134Vfs*10 | Frame Shift Del (DEL) | VAF 59/109 reads (54%) | called by mutect2, pindel*, varscan2
- LIN37 | c.191+1del | Frame Shift Del (DEL) | VAF 25/71 reads (35%) | called by mutect2, pindel, varscan2
- MROH1 | c.4438T>C p.C1480R | Missense Mutation (SNP) | VAF 35/74 reads (47%) | SIFT tolerated (0.07); PolyPhen benign (0); called by muse, mutect2, varscan2
- NBEAL1 | c.5010dup p.E1671* | Frame Shift Ins (INS) | VAF 15/44 reads (34%) | called by mutect2, pindel, varscan2
- ARL14EP | c.27C>T p.V9= | Silent (SNP) | VAF 132/298 reads (44%) | catalogued as rs994629542, COSV56343411; called by muse, mutect2, varscan2
- DCC | c.3534T>A p.S1178= | Silent (SNP) | VAF 22/41 reads (54%) | catalogued as COSV71439542; called by muse, mutect2, varscan2
- DHX57 | c.636A>G p.A212= | Silent (SNP) | VAF 63/111 reads (57%) | catalogued as COSV54890044; called by muse, mutect2, varscan2
- GALNS | c.1281C>T p.V427= | Silent (SNP) | VAF 68/226 reads (30%) | catalogued as COSV51939894; called by muse, mutect2, varscan2
- HK1 | c.504G>A p.L168= | Silent (SNP) | VAF 61/151 reads (40%) | catalogued as COSV53864526; called by muse, mutect2, varscan2
- HOGA1 | c.450C>T p.L150= | Silent (SNP) | VAF 30/78 reads (38%) | catalogued as COSV65706645; called by muse, mutect2, varscan2
- KDM2B | c.2434C>T p.L812= | Silent (SNP) | VAF 8/45 reads (18%) | catalogued as COSV65644135; called by muse, mutect2, varscan2
- PLK4 | c.2115T>C p.Y705= | Silent (SNP) | VAF 28/100 reads (28%) | catalogued as rs1286836497, COSV54638929; ClinVar: likely benign; called by muse, varscan2
- SLC44A3 | c.1338T>A p.S446= (on ENST00000271227 / NM_001114106.3; = p.S398= on NM_152369.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 21/68 reads (31%) | catalogued as COSV54733179; called by muse, mutect2
- TOPBP1 | c.3879G>A p.L1293= | Silent (SNP) | VAF 19/47 reads (40%) | catalogued as COSV53440455; called by muse, mutect2, varscan2
- ZFHX3 | c.11082C>A p.T3694= | Silent (SNP) | VAF 34/117 reads (29%) | catalogued as COSV51731402; called by muse, mutect2, varscan2
- ZNF14 | c.1833A>C p.G611= | Silent (SNP) | VAF 36/81 reads (44%) | catalogued as COSV59850991; called by muse, mutect2, varscan2
